Somatic mutation profile of tumor specimen TARGET-10-PANXZK-09A (aliquot TARGET-10-PANXZK-09A-01D) from TARGET case TARGET-10-PANXZK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,642 days).
Specimen TARGET-10-PANXZK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b935264-0347-4cee-b89c-39a51ca1d879.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANXZK-10A (Blood Derived Normal), aliquot TARGET-10-PANXZK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/204546cf-04c8-4e7f-9a28-cf73c8ac89b6

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Intron 1, RNA 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FKBP4 | c.1269C>A p.N423K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs879015932, COSV99133664; called by muse, mutect2
- H3C4 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV61911531, COSV61912198, COSV61912262; called by muse, varscan2
- H3C4 | c.168G>T p.Q56H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); catalogued as COSV61912132; called by muse, varscan2
- ITGA2 | c.1822G>T p.D608Y | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs528179659, COSV56857076; called by muse, mutect2, varscan2
- KCNH5 | c.2620C>T p.R874C | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs754436628, COSV59753363; called by muse, mutect2, varscan2
- MUC12 | c.12812G>A p.R4271H (on ENST00000379442; = p.R4128H on NM_001164462.1) | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated (0.23); catalogued as rs1362766181; called by muse, mutect2, varscan2
- PTK7 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1387686822; called by muse, mutect2
- DMD | c.1977A>C p.E659D | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- DNAJC2 | c.1393G>T p.A465S | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2
- DNAJC22 | c.933C>A p.D311E | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by muse, mutect2
- FBXL14 | c.374G>T p.S125I | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- HTR6 | c.629G>A p.R210K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- LIPH | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2
- NHSL2 | c.1462C>A p.P488T (on ENST00000510661; = p.P854T on NM_001013627.2) | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- PCDHGA7 | c.123del p.S43Pfs*35 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- TSSK3 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 75/145 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- AHNAK | c.9027G>A p.P3009= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as rs200863049, COSV57215789; called by muse, mutect2, varscan2
- FKRP | c.1365C>G p.A455= | Silent (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- KIAA0100 | c.915G>T p.L305= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- OSER1 | c.720G>T p.S240= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99667476; called by mutect2, varscan2
- TMEM31 | c.357C>T p.I119= | Silent (SNP) | VAF 27/142 reads (19%) | catalogued as COSV60327397; called by muse, mutect2, varscan2
- NADK | c.394-264G>A | Intron (SNP) | VAF 35/99 reads (35%) | catalogued as rs368645544; called by muse, varscan2
- PLA2G4B | c.-46C>A | 5'UTR (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2
- SLC25A48-AS1 | n.330T>A | RNA (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
